Somatic mutation profile of tumor specimen de439530-464e-481b-91ab-0685b9 (aliquot de439530-464e-481b-91ab-0685b9_D6) from CPTAC case 11CO008, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen de439530-464e-481b-91ab-0685b9: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9534e5fe-331a-4a33-84fb-61e28c5bbb99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 012baf0d-2c53-4409-91ec-2c7998 (Blood Derived Normal), aliquot 012baf0d-2c53-4409-91ec-2c7998_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8906a5c8-4ebf-4c5a-9585-92f2e0c9697e

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 33 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 33, Nonsense Mutation 7, 3'UTR 3, Splice Region 2, Frame Shift Del 2, 3'Flank 2, 5'Flank 1, In Frame Del 1, 5'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3815C>G p.S1272* | Nonsense Mutation (SNP) | VAF 52/230 reads (23%) | catalogued as rs863225348, CD106449, CM040676, COSV57348860, COSV57351844, COSV57380973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 125/225 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 128/299 reads (43%) | hotspot (GDC flag); catalogued as rs876658483, COSV52774899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAP3 | c.1619G>A p.R540Q | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs745323169, COSV57644079; called by muse, mutect2
- ACSM4 | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 152/306 reads (50%) | catalogued as rs746836708, COSV101257265; called by muse, mutect2, varscan2
- AMOTL1 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs778050282, COSV58569476; called by mutect2, varscan2
- ANKRD26 | c.4834G>A p.V1612M | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs751471164; called by muse, mutect2, varscan2
- ANKRD44 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs762390824, COSV56550727; called by muse, mutect2, varscan2
- BAIAP3 | c.3046G>A p.V1016I | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs376838060; called by muse, mutect2, varscan2
- BNC1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61756499, COSV61757336; called by muse, varscan2
- CDKN2AIP | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.508); catalogued as rs1274298170; called by muse, mutect2
- COL9A2 | c.1343G>A p.G448D | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65624023; called by muse, mutect2, varscan2
- CROCC | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs750711172, COSV100978271; called by muse, mutect2, varscan2
- CYP11B2 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 87/518 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.351); catalogued as rs148659506, COSV59994344; called by muse, mutect2, varscan2
- DCAF12L1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 138/429 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as COSV64421672; called by muse, mutect2, varscan2
- DNAJC18 | c.592G>T p.D198Y | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV57415077; called by muse, mutect2, varscan2
- DSCAML1 | c.4720G>A p.V1574I (on ENST00000321322; = p.V1514I on NM_020693.4) | Missense Mutation (SNP) | VAF 56/362 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs542233373, COSV58385941, COSV58402826; called by muse, varscan2
- FAM47A | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 8/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60500739; called by muse, mutect2
- FAT1 | c.12728C>G p.S4243* | Nonsense Mutation (SNP) | VAF 10/270 reads (4%) | catalogued as COSV71673345; called by muse, mutect2
- HEATR5B | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs759689284, COSV99250517; called by muse, mutect2, varscan2
- HGF | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 36/362 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV55946533, COSV99736844; called by muse, mutect2
- HOXD12 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 97/415 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV66832326; called by muse, mutect2, varscan2
- ITGA10 | c.1085C>A p.A362E | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs587650439; called by muse, mutect2, varscan2
- KCNH1 | c.2488G>A p.D830N (on ENST00000271751 / NM_172362.3; = p.D803N on NM_002238.4) | Missense Mutation (SNP) | VAF 110/387 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.048); catalogued as rs372532077; called by muse, mutect2, varscan2
- LCN10 | c.542G>A p.R181H (on ENST00000474369 / NM_001368089.1; = p.R194H on NM_001001712.3) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs532156338, COSV57910412; called by muse, mutect2, varscan2
- LRP1B | c.9067C>T p.H3023Y | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67263103; called by muse, varscan2
- MACROD2 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs779540577; called by muse, mutect2
- MAGEA11 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV60754166, COSV60754525; called by muse, mutect2, varscan2
- MORC1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759790452, COSV51713109; called by muse, mutect2, varscan2
- MTSS1 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV61500396; called by muse, mutect2, varscan2
- MYH6 | c.3575C>T p.A1192V | Missense Mutation (SNP) | VAF 60/505 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs765797952, COSV100676803; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.1954G>A p.G652R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767972373, COSV50752769; called by muse, mutect2, varscan2
- NRG3 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 120/358 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs903043829, COSV64560166; called by muse, mutect2, varscan2
- OR10R2 | c.58C>A p.Q20K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV63768732; called by muse, mutect2, varscan2
- PDK3 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1442646183, COSV64793902; called by muse, varscan2
- PHC1 | c.2309C>T p.P770L | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs144694464; called by muse, mutect2, varscan2
- PHKG1 | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1310237471; called by muse, mutect2
- PIGQ | c.2275G>A p.A759T | Missense Mutation (SNP) | VAF 95/408 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs572929607, COSV50320188; called by muse, mutect2, varscan2
- PTPRM | c.3214G>A p.G1072S | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138337205; called by muse, mutect2
- RHBDF1 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as rs769452521, COSV99244170; called by muse, mutect2, varscan2
- SCN3B | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); catalogued as rs1369842400, COSV100173905; called by muse, mutect2, varscan2
- SLC6A14 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781875319; called by muse, mutect2, varscan2
- SPDEF | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 28/431 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746647174, COSV65000583; called by muse, mutect2
- TMEM86A | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 116/456 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs775893136, COSV55010626; called by mutect2, varscan2
- TOPAZ1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs1371718823, COSV59075212; called by muse, mutect2, varscan2
- UBR4 | c.7497G>A p.E2499= | Splice Region (SNP) | VAF 34/123 reads (28%) | catalogued as rs1478501219, COSV64396049; called by muse, mutect2, varscan2
- VDR | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 35/410 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.652); catalogued as rs201676749; called by muse, mutect2
- ZDHHC1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs571642362, COSV62214588; called by muse, mutect2, varscan2
- ZHX3 | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 104/335 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.422); catalogued as rs747830614, COSV58390271; called by muse, mutect2, varscan2
- ZNF454 | c.1201C>T p.R401* | Nonsense Mutation (SNP) | VAF 30/222 reads (14%) | catalogued as rs756892601, COSV100195260; called by muse, mutect2, varscan2
- ZNF665 | c.902G>A p.R301Q (on ENST00000600412; = p.R366Q on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs766056086, COSV67214897; called by muse, mutect2, varscan2
- ZNF696 | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1344291851, COSV57526073; called by muse, varscan2
- ACER2 | c.779_780del p.Y260Cfs*37 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel
- AJUBA | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDOA | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- B4GAT1 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BTAF1 | c.4998A>C p.K1666N | Missense Mutation (SNP) | VAF 15/215 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2
- CASP1 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D2B | c.172T>A p.C58S | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2
- CCNT2 | c.100C>T p.L34F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- DIAPH2 | c.3040G>T p.E1014* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- EMC4 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- HELB | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ICE1 | c.195_197del p.R66del | In Frame Del (DEL) | VAF 10/57 reads (18%) | called by pindel, varscan2
- IQCA1 | c.1808A>G p.N603S | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- KIF5A | c.2323C>A p.Q775K | Missense Mutation (SNP) | VAF 26/425 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- LCOR | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- LRIG1 | c.1810A>G p.T604A | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- MCTP2 | c.479G>T p.S160I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MKS1 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NFKBIZ | c.1532G>T p.C511F | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PABPC1L2A | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PITPNM1 | c.1888del p.Q630Sfs*81 | Frame Shift Del (DEL) | VAF 13/86 reads (15%) | called by mutect2, pindel, varscan2
- PKHD1 | c.3657A>G p.I1219M | Missense Mutation (SNP) | VAF 205/442 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.419); called by muse, varscan2
- PPM1H | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRKD1 | c.1672+5G>C | Splice Region (SNP) | VAF 46/69 reads (67%) | called by muse, mutect2, varscan2
- RP1 | c.2107C>A p.L703I | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.274); called by muse, mutect2
- SLC18A3 | c.1508C>G p.P503R | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCERG1L | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THBD | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- TMEM200C | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- TTN | c.70974G>T p.K23658N (on ENST00000591111; = p.K16234N on NM_003319.4) | Missense Mutation (SNP) | VAF 50/467 reads (11%) | PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TTN | c.13304A>C p.K4435T (on ENST00000591111; = p.K4389T on NM_003319.4) | Missense Mutation (SNP) | VAF 50/306 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT3A1 | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.186); called by muse, mutect2
- ZNF556 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AFF2 | c.123C>T p.D41= | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as rs782561675, COSV60656285; called by muse, mutect2, varscan2
- ALPK2 | c.495C>T p.P165= | Silent (SNP) | VAF 31/205 reads (15%) | catalogued as rs1196793853; called by muse, mutect2, varscan2
- ANGPTL2 | c.453C>T p.N151= | Silent (SNP) | VAF 172/575 reads (30%) | catalogued as rs377308519, COSV99401386; called by muse, mutect2, varscan2
- BRINP3 | c.1792C>A p.R598= | Silent (SNP) | VAF 76/253 reads (30%) | catalogued as COSV66539636; called by muse, mutect2, varscan2
- C15orf39 | c.1689C>T p.P563= | Silent (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- C3 | c.276C>T p.A92= | Silent (SNP) | VAF 12/327 reads (4%) | called by muse, mutect2
- CDH5 | c.1947C>T p.G649= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- COL5A1 | c.3153C>T p.G1051= | Silent (SNP) | VAF 122/361 reads (34%) | called by muse, mutect2, varscan2
- DCHS1 | c.6909G>A p.V2303= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- DEFB128 | c.249C>A p.I83= | Silent (SNP) | VAF 91/367 reads (25%) | called by muse, mutect2, varscan2
- FCAR | c.348G>A p.E116= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- GCNT3 | c.1188G>A p.G396= | Silent (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- GPR45 | c.531G>A p.A177= | Silent (SNP) | VAF 78/306 reads (25%) | catalogued as COSV51523088; called by muse, mutect2, varscan2
- HUWE1 | c.10593G>A p.S3531= | Silent (SNP) | VAF 82/217 reads (38%) | catalogued as rs374253424, COSV53340409; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL34 | c.780G>A p.T260= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- MAPK8IP1 | c.1431C>T p.F477= | Silent (SNP) | VAF 63/413 reads (15%) | catalogued as rs746843201, COSV53798158; called by muse, mutect2, varscan2
- MINDY4 | c.2097C>T p.D699= | Silent (SNP) | VAF 122/213 reads (57%) | called by muse, mutect2, varscan2
- MN1 | c.756C>T p.S252= | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- NFKBIZ | c.1533C>T p.C511= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as rs370974986; called by muse, mutect2, varscan2
- NRXN3 | c.1830C>T p.N610= (on ENST00000557594 / NM_001272020.2; = p.N1034= on NM_004796.6) | Silent (SNP) | VAF 54/122 reads (44%) | catalogued as rs138628835; called by muse, mutect2, varscan2
- OPCML | c.612G>A p.A204= | Silent (SNP) | VAF 30/139 reads (22%) | catalogued as rs148098619; called by muse, varscan2
- PCDH17 | c.786C>A p.V262= | Silent (SNP) | VAF 48/576 reads (8%) | catalogued as rs142991646; called by muse, mutect2
- PCDHA13 | c.576A>G p.L192= | Silent (SNP) | VAF 73/282 reads (26%) | called by muse, mutect2, varscan2
- PCED1A | c.81G>A p.Q27= | Silent (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- PCSK2 | c.715C>A p.R239= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV52738706, COSV52741396; called by muse, mutect2
- PHF20 | c.2622C>T p.N874= | Silent (SNP) | VAF 57/162 reads (35%) | catalogued as rs190712704; called by muse, mutect2, varscan2
- PRTN3 | c.489C>T p.H163= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs778984949, COSV52256180; called by muse, mutect2, varscan2
- RAPGEF2 | c.2130A>G p.Q710= | Silent (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- SPSB4 | c.456C>T p.D152= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as rs1389791699, COSV60149009; called by muse, mutect2, varscan2
- TRMT12 | c.1257T>A p.I419= | Silent (SNP) | VAF 11/287 reads (4%) | called by muse, mutect2
- ZNF385D | c.378C>T p.S126= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs770695712, COSV55781068; called by muse, varscan2
- ZNF618 | c.870G>A p.P290= (on ENST00000374126 / NM_001318042.2; = p.P258= on NM_001318040.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/213 reads (4%) | catalogued as rs965213900; called by muse, mutect2
- ZNF737 | c.267G>A p.Q89= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV101417692, COSV71199874; called by muse, mutect2, varscan2
- ATG4A | c.*4C>T | 3'UTR (SNP) | VAF 38/107 reads (36%) | called by muse, mutect2, varscan2
- CEMIP | chr15:80952139 del CT | 3'Flank (DEL) | VAF 8/70 reads (11%) | catalogued as rs1360933231; called by pindel, varscan2
- DNAJC5G | chr2:27275190 C>T | 5'Flank (SNP) | VAF 6/116 reads (5%) | catalogued as rs955199926; called by muse, mutect2
- DTNA | c.*2626C>T | 3'UTR (SNP) | VAF 16/200 reads (8%) | catalogued as rs1375004051, COSV99311339; called by muse, mutect2
- FGFR3 | c.*974C>T | 3'UTR (SNP) | VAF 43/324 reads (13%) | catalogued as COSV53400987; called by muse, mutect2, varscan2
- GUCY2EP | n.1151A>G | RNA (SNP) | VAF 14/234 reads (6%) | catalogued as rs904468530; called by muse, mutect2
- MTCL1 | chr18:8831691 C>T | 3'Flank (SNP) | VAF 74/305 reads (24%) | catalogued as rs1320451811; called by muse, mutect2, varscan2
- SRRM3 | c.-19G>A | 5'UTR (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- UQCC1 | c.573+68C>T | Intron (SNP) | VAF 86/298 reads (29%) | called by muse, varscan2
